Somatic mutation profile of tumor specimen TCGA-DJ-A4UT-01A (aliquot TCGA-DJ-A4UT-01A-11D-A257-08) from TCGA case TCGA-DJ-A4UT, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 32.3 years (11,813 days).
Specimen TCGA-DJ-A4UT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85651e21-cbd8-4725-9c17-e8f808c8e9d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A4UT-10A (Blood Derived Normal), aliquot TCGA-DJ-A4UT-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db24a699-4825-41b3-9581-9891744b44e1

The open-access MAF lists 32 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 21, Silent 8, Splice Site 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA5 | c.3145-1G>C p.X1049_splice | Splice Site (SNP) | VAF 4/50 reads (8%) | catalogued as COSV67018012; called by muse, mutect2
- ABCA9 | c.2808G>C p.Q936H | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60628461; called by muse, mutect2, varscan2
- BCL2L12 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs763532112, COSV55863967; called by muse, mutect2, varscan2
- C6 | c.141C>A p.H47Q | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as COSV54713920; called by muse, mutect2, varscan2
- CNBD2 | c.1447G>C p.D483H (on ENST00000373973 / NM_001365709.1; = p.D479H on NM_080834.4) | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV62587481; called by muse, mutect2, varscan2
- EIF2AK2 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.566); catalogued as COSV51798035; called by muse, mutect2
- FBN1 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 45/331 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs534859193, COSV57324686; called by muse, mutect2, varscan2
- GBF1 | c.4879-2A>C p.X1627_splice (on ENST00000369983 / NM_001377137.1; = p.X1626_splice on NM_004193.3) | Splice Site (SNP) | VAF 19/78 reads (24%) | catalogued as COSV64147211; called by muse, mutect2, varscan2
- GRIN2B | c.4423G>A p.E1475K | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.97); PolyPhen benign (0.184); catalogued as COSV74206903; called by muse, mutect2, varscan2
- LNPEP | c.2173G>A p.D725N | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.588); catalogued as COSV51479659; called by muse, mutect2, varscan2
- LRRC19 | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV66259330, COSV66259675; called by muse, mutect2, varscan2
- PHKA2 | c.276G>A p.M92I | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.135); catalogued as COSV66055286; called by muse, mutect2
- PPP1R13L | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.053); catalogued as rs1433202682, COSV62909151; called by muse, mutect2, varscan2
- RAB33A | c.340G>T p.V114F | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57062709; called by muse, mutect2, varscan2
- RNF13 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as COSV53524422; called by muse, mutect2, varscan2
- SPATA2 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.559); catalogued as COSV56867572; called by muse, mutect2
- STT3A | c.2108C>T p.S703L | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV67065229; called by muse, mutect2
- TARBP1 | c.4588C>G p.L1530V | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV50179949; called by muse, mutect2, varscan2
- UGT2B7 | c.46T>A p.F16I | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs1560508238, COSV59444504; called by muse, mutect2, varscan2
- USH2A | c.14045G>C p.R4682T | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV56403661; called by muse, mutect2
- WDR33 | c.3409G>A p.D1137N | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.977); catalogued as COSV59253085; called by muse, mutect2
- ZNF528 | c.34G>T p.D12Y | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64619385, COSV64620446; called by muse, mutect2, varscan2
- ZNF560 | c.865G>C p.D289H | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV56865195, COSV56869927; called by muse, mutect2
- ZPBP | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 3/27 reads (11%) | catalogued as rs1207271910, COSV50429540; called by muse, mutect2
- ARHGAP4 | c.771C>T p.V257= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as COSV63132460; called by muse, mutect2, varscan2
- ASTN1 | c.3321C>T p.I1107= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV62501220; called by muse, mutect2, varscan2
- CHST10 | c.918G>A p.P306= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as rs371699053; called by muse, mutect2
- IDI2 | c.96T>C p.G32= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as rs929566148, COSV52988587; called by muse, mutect2, varscan2
- NPPA | c.330C>A p.L110= | Silent (SNP) | VAF 6/140 reads (4%) | catalogued as COSV56741906; called by muse, mutect2
- SLC25A45 | c.516G>T p.L172= | Silent (SNP) | VAF 21/149 reads (14%) | catalogued as COSV53684399; called by muse, mutect2, varscan2
- TGFBRAP1 | c.420C>T p.I140= | Silent (SNP) | VAF 29/167 reads (17%) | catalogued as COSV51514448; called by muse, mutect2, varscan2
- ZNF165 | c.606T>C p.I202= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as COSV66102691, COSV66102775; called by muse, mutect2, varscan2
